Somatic mutation profile of tumor specimen TCGA-D1-A0ZV-01A (aliquot TCGA-D1-A0ZV-01A-11D-A10M-09) from TCGA case TCGA-D1-A0ZV, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IB; Tumor grade: G2; Age at diagnosis: 58.5 years (21,374 days).
Specimen TCGA-D1-A0ZV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f907367-125e-4ea5-9c40-93f7d470d9ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D1-A0ZV-10A (Blood Derived Normal), aliquot TCGA-D1-A0ZV-10A-01D-A10M-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bbcb88c5-995b-40ca-a122-c3e8d2c91359

The open-access MAF lists 44 somatic variants for this specimen: 36 protein-altering or splice-affecting, 7 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 7, Frame Shift Del 3, Nonsense Mutation 3, 5'Flank 1, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTCF | c.1061C>T p.S354F | Missense Mutation (SNP) | VAF 30/127 reads (24%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV50461395, COSV50462411; called by muse, mutect2, varscan2
- PIK3CA | c.3140A>G p.H1047R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen benign (0.085); catalogued as rs121913279, CM153086, COSV55873195, COSV55873401, COSV55888015; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PTEN | c.389del p.R130Qfs*4 | Frame Shift Del (DEL) | VAF 20/79 reads (25%) | catalogued as rs121913292, CM981670, CM991081, COSV64288376, COSV64288604, COSV64290765, COSV64291054; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- AGO2 | c.692T>C p.I231T | Missense Mutation (SNP) | VAF 77/263 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.142); catalogued as COSV55050757; called by muse, mutect2, varscan2
- CDC45 | c.1070G>A p.R357H | Missense Mutation (SNP) | VAF 40/155 reads (26%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.961); catalogued as rs369554602; called by muse, mutect2, varscan2
- CDH18 | c.1045G>T p.G349* | Nonsense Mutation (SNP) | VAF 14/56 reads (25%) | catalogued as COSV56947701; called by muse, mutect2, varscan2
- CDK7 | c.22C>T p.R8W | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV56508340; called by muse, mutect2, varscan2
- CENPU | c.295C>T p.P99S | Missense Mutation (SNP) | VAF 98/363 reads (27%) | SIFT tolerated (0.16); PolyPhen benign (0.014); catalogued as COSV55657684, COSV55658715; called by muse, varscan2
- CHRNA4 | c.1105C>T p.R369W | Missense Mutation (SNP) | VAF 19/62 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.035); catalogued as rs201224423, COSV64719242; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CTCF | c.433G>T p.E145* | Nonsense Mutation (SNP) | VAF 30/106 reads (28%) | catalogued as COSV50468840, COSV50496297; called by muse, mutect2, varscan2
- CYP19A1 | c.1369C>T p.R457* | Nonsense Mutation (SNP) | VAF 15/58 reads (26%) | catalogued as rs72552260, CM004195, COSV53057103; called by muse, mutect2, varscan2
- DLGAP5 | c.451C>T p.R151W | Missense Mutation (SNP) | VAF 86/299 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.209); catalogued as rs369854908; called by muse, mutect2, varscan2
- DPY19L4 | c.1928T>C p.V643A | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen benign (0.197); catalogued as COSV68963537; called by muse, mutect2, varscan2
- EIF3A | c.3932G>C p.R1311T | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.419); catalogued as COSV60775560; called by muse, mutect2
- EPB41L2 | c.443C>A p.P148H | Missense Mutation (SNP) | VAF 99/316 reads (31%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV61356930, COSV61357821; called by muse, mutect2, varscan2
- FLNC | c.1209G>A p.A403= | Splice Region (SNP) | VAF 17/64 reads (27%) | catalogued as rs746938160, COSV57961529; called by muse, mutect2, varscan2
- FNIP2 | c.2839C>T p.L947F | Missense Mutation (SNP) | VAF 6/98 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV52443785; called by muse, mutect2
- GABRG1 | c.1303C>T p.R435C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as rs779053780, COSV54949711, COSV54954783; called by muse, mutect2, varscan2
- GRIFIN | c.76G>A p.D26N | Missense Mutation (SNP) | VAF 6/29 reads (21%) | SIFT tolerated (0.77); PolyPhen benign (0.138); catalogued as COSV101321772, COSV101321776; called by muse, mutect2, varscan2
- H2BC5 | c.283A>G p.I95V | Missense Mutation (SNP) | VAF 46/144 reads (32%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); catalogued as COSV56802928; called by muse, mutect2, varscan2
- IFFO1 | c.1354G>A p.E452K (on ENST00000396840 / NM_001330324.2; = p.E455K on NM_080730.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 35/124 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.561); catalogued as COSV60738776; called by muse, mutect2, varscan2
- IL37 | c.520G>A p.G174R | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT tolerated (0.07); PolyPhen benign (0.11); catalogued as rs1160489801, COSV54492360, COSV99051663; called by muse, mutect2, varscan2
- NLRP10 | c.1064G>A p.G355D | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.885); catalogued as rs751286580, COSV60780146; called by muse, mutect2, varscan2
- PLXNB2 | c.430G>A p.V144M | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63782327; called by muse, mutect2, varscan2
- PRICKLE3 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV66235291; called by muse, mutect2, varscan2
- PSKH1 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated (0.18); PolyPhen benign (0.249); catalogued as rs1000942376, COSV52123429; called by muse, mutect2, varscan2
- RNF114 | c.203G>A p.R68H | Missense Mutation (SNP) | VAF 17/73 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs758000156, COSV54870638; called by muse, mutect2, varscan2
- SEMA5B | c.449G>A p.S150N | Missense Mutation (SNP) | VAF 41/118 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.058); catalogued as COSV52104820; called by muse, mutect2, varscan2
- SHANK1 | c.971G>A p.R324Q | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.464); catalogued as rs759365241, COSV53258283; called by muse, mutect2, varscan2
- TAB3 | c.1679G>T p.R560I | Missense Mutation (SNP) | VAF 27/93 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as COSV55839510; called by muse, mutect2, varscan2
- TSC2 | c.2207C>T p.A736V | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.992); catalogued as rs764259520, COSV54774830; ClinVar: benign; called by muse, mutect2, varscan2
- UNC45B | c.2225G>T p.G742V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.231); catalogued as rs756957061, COSV52099109; called by mutect2, varscan2
- WDR7 | c.3338T>A p.I1113N | Missense Mutation (SNP) | VAF 29/81 reads (36%) | SIFT tolerated (0.41); PolyPhen benign (0.094); catalogued as rs777481068, COSV54353480; called by muse, mutect2, varscan2
- TAF2 | c.1225del p.T409Lfs*27 | Frame Shift Del (DEL) | VAF 22/110 reads (20%) | called by mutect2, pindel, varscan2
- TLE1 | c.623_624insTT p.R209* | Frame Shift Ins (INS) | VAF 98/367 reads (27%) | called by mutect2, pindel, varscan2
- TXLNA | c.1637_1638del p.A546Vfs*27 | Frame Shift Del (DEL) | VAF 8/16 reads (50%) | called by mutect2, varscan2
- BICD2 | c.915C>T p.H305= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as rs373858530; called by muse, mutect2, varscan2
- C2orf68 | c.336C>T p.Y112= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as rs767998112, COSV60472828; called by muse, mutect2, varscan2
- CALCR | c.126C>T p.V42= | Silent (SNP) | VAF 15/64 reads (23%) | catalogued as rs754056336, COSV64010794; called by muse, mutect2, varscan2
- GLUD1 | c.240C>T p.I80= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV53280432; called by muse, mutect2, varscan2
- GNPTAB | c.1794C>T p.I598= | Silent (SNP) | VAF 69/259 reads (27%) | catalogued as rs1318081018, COSV68449860; called by muse, mutect2, varscan2
- GPR50 | c.709C>T p.L237= | Silent (SNP) | VAF 59/186 reads (32%) | catalogued as COSV54440651; called by muse, mutect2, varscan2
- ITGAX | c.2481G>A p.L827= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as COSV51649571; called by muse, mutect2, varscan2
- CUX1 | chr7:101816033 G>A | 5'Flank (SNP) | VAF 7/47 reads (15%) | catalogued as rs747699127, COSV52909813; called by muse, mutect2, varscan2
